Somatic mutation profile of tumor specimen MP2PRT-PATYVP-TMP1-A (aliquot MP2PRT-PATYVP-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PATYVP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.7 years (3,525 days).
Specimen MP2PRT-PATYVP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b0ad545-e049-4b9a-b262-5433d9b8038a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATYVP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATYVP-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61bfad44-affc-4843-b272-7ecf0c767819

The open-access MAF lists 26 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 5, In Frame Ins 3, Frame Shift Ins 1, Nonsense Mutation 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EZH2 | c.2172dup p.D725* (on ENST00000460911 / NM_001203247.2; = p.D730* on NM_004456.5) | Frame Shift Ins (INS) | VAF 88/377 reads (23%) | catalogued as rs797045568; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTPN11 | c.215C>A p.A72D | Missense Mutation (SNP) | VAF 100/346 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as rs121918454, CM013417, COSV61005613, COSV61008344, COSV61012146; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ASTN1 | c.3415G>A p.V1139M | Missense Mutation (SNP) | VAF 209/473 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs138978807; called by muse, mutect2, varscan2
- DDX25 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 116/340 reads (34%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.992); catalogued as rs375780207; called by muse, varscan2
- FRAS1 | c.1624G>A p.G542S | Missense Mutation (SNP) | VAF 132/665 reads (20%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as rs745735390, COSV53653345; called by muse, mutect2, varscan2
- HCRTR2 | c.984A>T p.R328S | Missense Mutation (SNP) | VAF 89/328 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.173); catalogued as COSV63798581; called by muse, mutect2, varscan2
- KIAA2012 | c.2470G>A p.G824R | Missense Mutation (SNP) | VAF 91/242 reads (38%) | SIFT tolerated (0.75); catalogued as rs1407535686; called by muse, mutect2, varscan2
- MAGEB17 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 33/391 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as rs1377784276; called by muse, mutect2
- SLC22A9 | c.1652C>T p.T551M | Missense Mutation (SNP) | VAF 70/279 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142543443, CM124408; called by muse, mutect2, varscan2
- SLC5A12 | c.1732C>T p.R578W | Missense Mutation (SNP) | VAF 90/306 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs187905818, COSV68448221; called by muse, mutect2, varscan2
- C19orf44 | c.1638G>T p.K546N | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- CHD8 | c.2073_2075dup p.D691_K692insN (on ENST00000646647 / NM_001170629.2; = p.D412_K413insN on NM_020920.4) | In Frame Ins (INS) | VAF 65/344 reads (19%) | called by mutect2, pindel, varscan2
- CNTN1 | c.1280C>A p.A427D | Missense Mutation (SNP) | VAF 100/362 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CREBBP | c.4518_4519insGGG p.M1506_L1507insG | In Frame Ins (INS) | VAF 110/359 reads (31%) | called by mutect2, pindel, varscan2
- DOK4 | c.559T>C p.Y187H | Missense Mutation (SNP) | VAF 105/321 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FSIP2 | c.20098C>T p.P6700S | Missense Mutation (SNP) | VAF 86/306 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- MTHFR | c.1280G>A p.S427N | Missense Mutation (SNP) | VAF 94/352 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- NCKAP1L | c.1234G>T p.E412* | Nonsense Mutation (SNP) | VAF 99/324 reads (31%) | called by muse, mutect2, varscan2
- UHRF1 | c.1367_1368insGACCCCATTCGACGG p.G456_A457insTPFDG (on ENST00000612630 / NM_001290050.1; = p.G469_A470insTPFDG on NM_013282.4) | In Frame Ins (INS) | VAF 42/182 reads (23%) | called by mutect2, pindel, varscan2
- IGKV1OR2-108 | chr2:113406871 TTCACAGTGTTACAAGCCATAACAA>AGG | Silent (DEL) | VAF 52/128 reads (41%) | called by pindel, varscan2*
- PLCE1 | c.3579C>T p.H1193= | Silent (SNP) | VAF 107/383 reads (28%) | catalogued as rs368956195; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC25A10 | c.450C>T p.R150= | Silent (SNP) | VAF 146/430 reads (34%) | catalogued as rs530579141; called by muse, mutect2, varscan2
- SPHKAP | c.2811C>T p.V937= | Silent (SNP) | VAF 48/173 reads (28%) | catalogued as rs1334084304, COSV60876713; called by muse, mutect2, varscan2
- TENM3 | c.6690C>T p.D2230= | Silent (SNP) | VAF 103/549 reads (19%) | catalogued as rs369647107; called by muse, mutect2, varscan2
- ESRRB | c.-132+4847C>A | Intron (SNP) | VAF 147/606 reads (24%) | called by muse, mutect2, varscan2
- IGLV4-60 | chr22:22162681 ins TAAGTTTCC | 3'Flank (INS) | VAF 29/66 reads (44%) | called by pindel, varscan2
